FM case AD8785 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/765de1a1-0f66-4901-b253-4329e9cd5f45

Male, 70.6 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the bladder; primary biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
